Somatic mutation profile of tumor specimen bc574f73-89ba-44d7-992e-82622c (aliquot bc574f73-89ba-44d7-992e-82622c_D6_1) from CPTAC case 11CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen bc574f73-89ba-44d7-992e-82622c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9dcce4e-2d53-4490-869c-42b91d4aaccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6dde8e08-dd45-40f2-91ef-224298 (Blood Derived Normal), aliquot 6dde8e08-dd45-40f2-91ef-224298_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbf02c6e-9c9f-4668-8201-4891a1d5876f

The open-access MAF lists 78 somatic variants for this specimen: 48 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 4, Intron 3, 5'UTR 3, Frame Shift Ins 2, RNA 2, Splice Site 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 15/181 reads (8%) | catalogued as rs5030852, CD068113, CS1314673, CS910454; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- AMER1 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 32/364 reads (9%) | catalogued as CM117716, COSV57662882, COSV57669568; called by muse, mutect2
- APC | c.3724C>T p.Q1242* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as rs1460397656, CM061638, COSV99965141; called by muse, mutect2, varscan2
- ARHGAP32 | c.3943G>T p.A1315S (on ENST00000310343 / NM_001378025.1; = p.A966S on NM_014715.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as COSV100088369; called by muse, mutect2
- ARHGAP36 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52269582, COSV99357785; called by muse, mutect2, varscan2
- DCLK1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs745600254, COSV55206432; called by muse, mutect2, varscan2
- DMBT1 | c.5965C>T p.R1989* (on ENST00000338354 / NM_001377530.1; = p.R1232* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 40/291 reads (14%) | catalogued as rs143073434, COSV100353895; called by muse, mutect2, varscan2
- GRIA1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as rs138238382, COSV53607690; called by muse, mutect2
- LAX1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs776113092, COSV65849234; called by muse, mutect2, varscan2
- NOTCH1 | c.6121G>T p.V2041L | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV53102797, COSV53105244; called by muse, mutect2, varscan2
- OCSTAMP | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 23/201 reads (11%) | catalogued as COSV54098995; called by muse, mutect2, varscan2
- OR51B5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs754820149, COSV56175739; called by muse, mutect2, varscan2
- OSBPL5 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767142123; called by muse, varscan2
- PCDHB6 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.417); catalogued as COSV50719581; called by muse, mutect2, varscan2
- PCDHGA6 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1194415432, COSV53906621; called by muse, mutect2
- SHISA2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776073587, COSV60111177; called by muse, varscan2
- SUPT16H | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99360049; called by muse, mutect2, varscan2
- TENM1 | c.5180G>A p.R1727H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as rs781291485; called by muse, mutect2, varscan2
- TEX26 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs775005047, COSV66839450; called by muse, mutect2, varscan2
- TRARG1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763167536, COSV61563085; called by muse, mutect2, varscan2
- ZFR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs185400185, COSV53599530, COSV53604876; called by muse, mutect2
- ZNF583 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52400876; called by muse, mutect2
- CNTNAP3 | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- COPB2 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRB1 | c.349A>C p.N117H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DOCK8 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2
- GRIK2 | c.2274dup p.I759Yfs*4 | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- GUCY2D | c.2576+3G>T | Splice Region (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- KLHL34 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRP1B | c.1207_1208insT p.N403Ifs*2 | Frame Shift Ins (INS) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- LYPD3 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by mutect2, varscan2
- NFRKB | c.3476C>T p.A1159V (on ENST00000446488 / NM_001143835.2; = p.A1184V on NM_006165.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NUP153 | c.2165T>C p.V722A | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PEDS1 | c.187del p.H63Ifs*80 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- PEG3 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHA5 | c.2641-1G>T p.X881_splice | Splice Site (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- PRKCA | c.1505C>G p.P502R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABGGTA | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- RHOT1 | c.654C>A p.N218K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2
- RNF121 | c.620C>A p.T207N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.59); called by muse, mutect2
- RPS6KA3 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SH3TC1 | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 3/56 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- SLC35A2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, varscan2
- SLC7A4 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TMEM143 | c.183G>T p.R61S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- UBE2Q1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.12960C>A p.P4320= (on ENST00000280772 / NM_001320874.2; = p.P944= on NM_001149.3) | Silent (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2
- ATM | c.6909G>A p.K2303= | Silent (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- CBL | c.1014G>A p.L338= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs1390761732; called by muse, mutect2, varscan2
- CD14 | c.582G>A p.P194= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- GART | c.2559G>A p.A853= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs763016241, COSV101111318; called by muse, mutect2, varscan2
- GGT7 | c.282C>T p.S94= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs972812335, COSV100321802; called by muse, mutect2, varscan2
- HTR5A | c.195C>T p.I65= | Silent (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- KCNE4 | c.411G>A p.P137= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs545347626; called by muse, mutect2, varscan2
- LCN1 | c.417G>A p.K139= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- MEST | c.81G>A p.A27= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs1298623099; called by muse, mutect2, varscan2
- MYH2 | c.4500G>A p.Q1500= | Silent (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1614G>A p.P538= | Silent (SNP) | VAF 49/390 reads (13%) | called by muse, varscan2
- POM121L12 | c.129G>A p.T43= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs767944025, COSV68692212; called by muse, mutect2, varscan2
- PRKG1 | c.1101C>T p.F367= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs752325371, COSV64777178; called by muse, mutect2, varscan2
- SIGIRR | c.1077G>A p.R359= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- SLC13A2 | c.117G>A p.A39= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs181965873, COSV58995291; called by muse, mutect2, varscan2
- SNED1 | c.1635C>T p.C545= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs750589443, COSV60022408; called by muse, mutect2, varscan2
- STMND1 | c.172C>T p.L58= | Silent (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- TNS1 | c.5142C>T p.N1714= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- TRIM16 | c.1116G>A p.A372= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1293306011; called by muse, mutect2, varscan2
- ZNF616 | c.1302G>A p.Q434= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, varscan2
- ACSL4 | c.-358G>A | 5'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.105+444G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1440818288; called by muse, mutect2
- ATP2B2 | c.*209C>T | 3'UTR (SNP) | VAF 29/236 reads (12%) | catalogued as rs146846448; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.447C>T | RNA (SNP) | VAF 30/330 reads (9%) | catalogued as rs747992887; called by muse, mutect2
- HOXA1 | c.-26C>T | 5'UTR (SNP) | VAF 15/91 reads (16%) | catalogued as COSV56066589; called by muse, mutect2, varscan2
- PABPC4L | c.-134C>G | 5'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- PKD1L2 | n.527G>A | RNA (SNP) | VAF 8/79 reads (10%) | catalogued as rs745935689; called by mutect2, varscan2
- SPACA7 | c.94+2214C>T | Intron (SNP) | VAF 10/152 reads (7%) | catalogued as rs930998070; called by muse, mutect2
- TTN | c.10360+4134A>G | Intron (SNP) | VAF 42/411 reads (10%) | catalogued as rs1474598156; called by muse, mutect2, varscan2
